Somatic mutation profile of tumor specimen MP2PRT-PARUCC-TMP1-A (aliquot MP2PRT-PARUCC-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PARUCC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.8 years (3,581 days).
Specimen MP2PRT-PARUCC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48ac86bb-2a70-42a9-abee-716566003118.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUCC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUCC-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c661858-1834-4683-bbd4-43a713d459db

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, In Frame Ins 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2362G>T p.E788* | Nonsense Mutation (SNP) | VAF 34/515 reads (7%) | catalogued as rs1402270258, COSV60104043, COSV60109346; called by muse, mutect2
- ITGB5 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 153/515 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs567246765; called by muse, mutect2, varscan2
- KRAS | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 216/397 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55502236; called by muse, mutect2, varscan2
- LCP2 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.349); catalogued as rs770217056, COSV50448131; called by muse, mutect2, varscan2
- PAX5 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 174/394 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63905005, COSV63910543; called by muse, mutect2, varscan2
- H2AC16 | c.62G>C p.R21P | Missense Mutation (SNP) | VAF 135/423 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- KBTBD12 | c.353_354insGGA p.S118delinsRD | In Frame Ins (INS) | VAF 79/288 reads (27%) | called by mutect2, pindel, varscan2
- KMT2D | c.12807_12808insGGCC p.Q4270Gfs*65 | Frame Shift Ins (INS) | VAF 182/588 reads (31%) | called by mutect2, pindel*, varscan2
- NXF1 | c.28+1_28+2insCCC p.X10_splice | Splice Site (INS) | VAF 225/735 reads (31%) | called by mutect2, pindel*, varscan2*
- NXPH2 | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.23); called by muse, mutect2
- PCDHAC1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 102/503 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- PHACTR2 | c.927_929dup p.P310dup | In Frame Ins (INS) | VAF 130/480 reads (27%) | called by pindel, varscan2
- SH2B3 | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 286/784 reads (36%) | called by muse, varscan2
- GRIK3 | c.2151G>A p.A717= | Silent (SNP) | VAF 145/511 reads (28%) | catalogued as rs1287829894, COSV66147237; called by muse, mutect2, varscan2
- KAT6B | c.5385C>T p.Y1795= | Silent (SNP) | VAF 21/576 reads (4%) | catalogued as rs767336647; ClinVar: uncertain significance; called by muse, mutect2
- NOTCH3 | c.1257C>T p.C419= | Silent (SNP) | VAF 124/587 reads (21%) | catalogued as rs1357572876, CM159180; called by muse, mutect2, varscan2
- TEX15 | c.4785G>A p.A1595= (on ENST00000256246; = p.A1978= on NM_001350162.2) | Silent (SNP) | VAF 118/273 reads (43%) | catalogued as rs375928810; called by muse, mutect2, varscan2
- NEURL4 | chr17:7315610 del GAGA | 3'Flank (DEL) | VAF 103/592 reads (17%) | called by mutect2, pindel, varscan2
